Somatic mutation profile of tumor specimen TARGET-15-SJMPAL046466-09A.1 (aliquot TARGET-15-SJMPAL046466-09A.1-01D) from TARGET case TARGET-15-SJMPAL046466, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.3 years (851 days).
Specimen TARGET-15-SJMPAL046466-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54feea42-a043-493e-bb06-7002580c67c5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL046466-14A.1 (Bone Marrow Normal), aliquot TARGET-15-SJMPAL046466-14A.1-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4488421a-6021-4cfd-be4b-3247fd0e6324

The open-access MAF lists 6 somatic variants for this specimen: 6 protein-altering or splice-affecting.
By variant classification: Missense Mutation 6.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRB | c.4988G>A p.R1663Q | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as rs139546127, COSV54237615; called by muse, mutect2, varscan2
- TMEM125 | c.622C>A p.R208S | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV71326899; called by muse, mutect2
- ZNF518A | c.2460C>A p.H820Q | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs782292780; called by muse, mutect2
- MED20 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.096); called by muse, mutect2
- RAB1A | c.291G>T p.E97D | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- SETDB2 | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
